Gene-level copy-number profile of tumor specimen TCGA-VM-A8CD-01A from TCGA case TCGA-VM-A8CD, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 58.0 years (21,200 days).
Specimen TCGA-VM-A8CD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.277c58af-3cae-4335-80f3-32a728a5818d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VM-A8CD-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21fb1a17-4d0e-44e3-bde4-a2abe25ed976

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 14,875; copy number 2: 44,846; copy number 3: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VM-A8CD-01A-11D-A36N-01): tumor purity 0.66, ploidy 1.78, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,695,176–22,214,672, 17 genes: KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr9:22,646,200–29,826,711, 61 genes (broad region; genes not listed).
- chr10:120,851,305–120,985,596, 4 genes (within-gene range 0–1): WDR11, AC010998.2, AC010998.1, AC010998.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,489. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
